Somatic mutation profile of tumor specimen C3L-05819-54 (aliquot CPT0341900002) from CPTAC case C3L-05819, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 80.1 years (29,260 days).
Specimen C3L-05819-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 668e73e3-87d5-4ca9-a321-313457783e0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05819-50 (Buccal Cell Normal), aliquot CPT0341870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ad00c65-b3e2-45e8-9058-7c49dd0d241a

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'Flank 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 30/63 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DACT2 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs995544811, COSV100829347; called by muse, mutect2
- TMEM94 | c.1176dup p.T393Dfs*55 | Frame Shift Ins (INS) | VAF 22/103 reads (21%) | catalogued as rs746649748; called by mutect2, pindel, varscan2
- CACNA1G | c.2808G>A p.T936= | Silent (SNP) | VAF 55/138 reads (40%) | catalogued as rs767911203, COSV61730413; called by muse, mutect2, varscan2
- PDP1 | chr8:93916921 G>C | 5'Flank (SNP) | VAF 45/96 reads (47%) | called by muse, varscan2
